MMRF case MMRF_1628 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2a4e21b2-79af-43de-9a17-58a12949757c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.7 years (23,277 days); ISS stage: I; Days to last known disease status: 1,223 days (3.3 years); Days to last follow up: 1,223 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 404 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 430 days (1.2 years); Days to treatment end: 1,027 days (2.8 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 430 days (1.2 years); Days to treatment end: 641 days (1.8 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,158 days (3.2 years); Days to treatment end: 1,158 days (3.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,159 days (3.2 years); Days to treatment end: 1,159 days (3.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22 (ECOG 1): M Protein 5.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.096 mg/dL; Immunoglobulin G 68.7 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.14 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 11.7 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 0.13 mg/dL.
- Day 103 (ECOG 0): M Protein 2.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.105 mg/dL; Immunoglobulin G 31.8 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 9.3 g/dL; Glucose 5.61 mmol/L.
- Day 200 (ECOG 0): M Protein 3.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.096 mg/dL; Immunoglobulin G 34.2 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 9.2 g/dL; Glucose 3.14 mmol/L.
- Day 286 (ECOG 0): M Protein 1.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.625 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 8 g/dL; Glucose 3.08 mmol/L.
- Day 367 (ECOG 0): M Protein 1.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.628 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.4 mmol/L.
- Day 430 (ECOG 0): M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.072 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 2.75 mmol/L.
- Day 500 (ECOG 0): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.139 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.14 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.13 mmol/L.
- Day 607 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.535 mg/dL; Immunoglobulin G 8.49 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 2.86 mmol/L.
- Day 691 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.524 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.13 mmol/L.
- Day 782 (ECOG 0): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.638 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 4.4 mmol/L.
- Day 845 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.721 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.536 mg/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.52 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 4.84 mmol/L.
- Day 917 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.795 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.226 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 3.52 mmol/L.
- Day 1,050 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.469 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.17 mmol/L.
- Day 1,146: M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.644 mg/dL; Immunoglobulin G 6.6 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 2.31 mmol/L.
- Day 1,223 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.435 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.661 mg/dL; Immunoglobulin G 5.8 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day -22: Weight: 53 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1628_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_1628_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
